Gene-level copy-number profile of tumor specimen TCGA-ZS-A9CF-02A from TCGA case TCGA-ZS-A9CF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 64.4 years (23,510 days).
Specimen TCGA-ZS-A9CF-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.57aa6c9a-22c3-470a-b775-0531e304ab99.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZS-A9CF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 374 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/47ebcdf9-3dac-4a18-a737-457cba65c2e0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 2,669; copy number 2: 8,780; copy number 3: 7,368; copy number 4: 30,703; copy number 5: 5,356; copy number 6: 2,330; copy number 7: 981; copy number 8: 1,043; copy number 9: 156; copy number 10: 804; copy number 11: 18; copy number 12: 16; copy number 13: 2; copy number 14: 10; copy number 15: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZS-A9CF-02A-11D-A381-01): tumor purity 0.93, ploidy 3.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:96,199,840–96,521,717, 2 genes (within-gene range 0–2): UFL1-AS1, RN7SL797P.
- chr7:150,791,285–150,805,118, 2 genes: TMEM176B, TMEM176A.
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–3): AC092821.1, AC092821.2.
- chr17:9,171,068–9,179,118, 1 gene: AC005695.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,011 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:56,718,789–56,918,223, 3 genes, copy number 11: FYB2, AL360295.1, C8A.
- chr1:151,399,560–151,401,937, 1 gene, copy number 9: PSMB4.
- chr1:161,184,302–178,484,147, 352 genes, copy number 10–15 (within-gene range 6–17) (broad region; genes not listed).
- chr1:178,411,616–196,884,793, 261 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr1:196,943,738–204,829,274, 199 genes, copy number 9–12 (broad region; genes not listed).
- chr1:211,492,255–211,492,917, 1 gene, copy number 9: AC105275.1.
- chr2:200,678,233–200,748,040, 3 genes, copy number 9 (within-gene range 9–11): AOX3P, AOX3P-AOX2P, LINC01792.
- chr2:233,354,494–233,472,104, 2 genes, copy number 9 (within-gene range 4–9): DGKD, Y_RNA.
- chr3:142,449,007–142,591,791, 5 genes, copy number 10: ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143.
- chr3:161,083,883–161,253,532, 3 genes, copy number 15 (within-gene range 6–15): B3GALNT1, NMD3, AC108738.1.
- chr4:76,435,229–76,783,253, 1 gene, copy number 9 (within-gene range 5–9): SHROOM3.
- chr4:76,532,222–76,898,144, 8 genes, copy number 9: RNU6-145P, MIR4450, MIR548AH, SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB.
- chr4:108,650,585–108,774,020, 5 genes, copy number 14: OSTC, RNU6-431P, AC107071.1, ETNPPL, AC097473.1.
- chr5:1,173,141–1,178,605, 1 gene, copy number 9: CTD-3080P12.3.
- chr6:2,227,803–2,525,976, 5 genes, copy number 9 (within-gene range 8–9): AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1.
- chr6:3,831,933–3,894,292, 3 genes, copy number 10 (within-gene range 5–10): AL391422.3, AL391422.2, FAM50B.
- chr6:5,085,341–5,829,192, 7 genes, copy number 11 (within-gene range 6–11): PPP1R3G, LYRM4, MIR3691, FARS2, AL121978.1, AL021328.1, HNRNPA1P37.
- chr6:43,770,184–43,852,333, 5 genes, copy number 14: VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1.
- chr6:78,604,467–78,946,440, 3 genes, copy number 9 (within-gene range 2–9): AL121718.1, AL450327.1, IRAK1BP1.
- chr8:100,380,486–100,464,613, 1 gene, copy number 11 (within-gene range 4–11): AP003472.1.
- chr8:100,427,559–100,432,726, 1 gene, copy number 11: AP003472.2.
- chr10:111,787,233–112,446,917, 9 genes, copy number 9–10 (within-gene range 5–19): AL136119.1, GPAM, TECTB, MIR6715B, MIR6715A, GUCY2GP, ACSL5, AL157786.1, ZDHHC6.
- chr10:112,548,632–112,548,872, 1 gene, copy number 10: AC022018.1.
- chr10:121,989,163–122,254,545, 1 gene, copy number 9 (within-gene range 4–9): TACC2.
- chr10:122,145,106–122,514,907, 8 genes, copy number 9 (within-gene range 4–9): AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1.
- chr12:56,101,331–56,316,059, 21 genes, copy number 10 (within-gene range 5–10): AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1.
- chr13:52,128,891–52,159,861, 2 genes, copy number 13 (within-gene range 7–13): AL139082.1, NEK3.
- chr14:105,736,343–106,318,236, 93 genes, copy number 9 (broad region; genes not listed).
- chr17:46,029,916–46,225,389, 1 gene, copy number 11 (within-gene range 5–11): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 11: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 290. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
